Gene-level copy-number profile of tumor specimen TCGA-DX-AB2H-01A from TCGA case TCGA-DX-AB2H, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 81.0 years (29,569 days).
Specimen TCGA-DX-AB2H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.9efff8a5-949d-4ad2-8d08-dfce8d3239f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b77ebf2f-35ca-4d2a-a0e0-eed44cde58d4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,573; copy number 2: 50,921; copy number 3: 833; copy number 4: 18; copy number 5: 18; copy number 6: 38; copy number 7: 23; copy number 8: 37; copy number 9: 7; copy number 10: 15; copy number 11: 83; copy number 12: 11; copy number 13: 3; copy number 14: 14; copy number 16: 17; copy number 17: 5; copy number 18: 14; copy number 19: 12; copy number 20: 7; copy number 21: 8; copy number 22: 63; copy number 23: 29; copy number 24: 16; copy number 25: 25; copy number 33: 6; copy number 35: 10; copy number 37: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB2H-01A-11D-A38Y-01): tumor purity 0.99, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 473 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:70,144,805–71,081,289, 20 genes, copy number 11–23: LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1, CTH, Metazoa_SRP, AL354872.1, CHORDC1P5, CASP3P1, LINC01788, AL513285.1, PTGER3, AL031429.1, AL031429.2, ZRANB2-AS1, ZRANB2, MIR186.
- chr1:71,367,054–71,367,303, 1 gene, copy number 14: AL358453.1.
- chr1:71,570,956–71,573,558, 1 gene, copy number 5: AL354949.1.
- chr1:72,636,547–74,198,187, 13 genes, copy number 5–7 (within-gene range 2–7): AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360, LINC02238, RNA5SP50, AL591463.1, RNU4ATAC8P, LRRIQ3.
- chr1:225,401,502–225,428,925, 1 gene, copy number 10: LBR.
- chr1:235,447,190–236,552,981, 32 genes, copy number 11 (within-gene range 2–11): B3GALNT2, MTCYBP14, MTND6P14, MTND5P19, MTND4P10, MTND4LP21, MTND3P8, MTCO3P46, GNG4, FO393422.1, AL583844.1, LYST, LDHAP2, LYST-AS1, MIR1537, RNU6-968P, AL139161.1, LINC02768, NID1, Y_RNA, AL122018.1, AL122018.2, GPR137B, ERO1B, RNU2-70P, AL450309.1, EDARADD, ENO1P1, LGALS8, LGALS8-AS1, AL359921.2, AL359921.1.
- chr1:238,777,049–238,779,200, 1 gene, copy number 9: MIPEPP2.
- chr1:244,352,635–244,731,586, 10 genes, copy number 16: C1orf100, AL645465.1, TGIF2P1, ADSS2, CATSPERE, CYCSP5, DESI2, AL451007.1, AL451007.3, AL451007.2.
- chr1:247,294,835–247,331,846, 2 genes, copy number 11 (within-gene range 2–11): Y_RNA, ZNF496.
- chr2:193,867,722–196,593,684, 28 genes, copy number 5–6 (within-gene range 1–11): AC074290.1, AC068135.2, AC068135.1, GLULP6, HNRNPA1P47, LINC01821, AC106883.1, AC073973.1, Metazoa_SRP, AC006196.1, LINC01790, AC010983.1, AC104823.1, AC064834.1, RNU6-169P, LINC01825, LINC01827, SLC39A10, AHCYP5, RNU6-915P, DNAH7, E2F3P2, AC114760.1, STK17B, AC114760.2, HECW2, HECW2-AS1, RN7SL820P.
- chr7:115,503,367–116,508,541, 14 genes, copy number 18: POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP.
- chr11:77,128,246–77,215,241, 1 gene, copy number 9: MYO7A.
- chr12:37,575,587–38,589,812, 14 genes, copy number 7–20: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2.
- chr12:38,994,803–39,908,300, 11 genes, copy number 23 (within-gene range 3–23): AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40.
- chr12:40,068,243–40,570,832, 9 genes, copy number 19: RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P.
- chr12:41,188,320–43,661,101, 40 genes, copy number 8–11 (within-gene range 8–23): PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17.
- chr12:44,498,616–47,079,959, 38 genes, copy number 6–24 (within-gene range 5–24): AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2.
- chr12:47,346,166–47,593,440, 7 genes, copy number 12: AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1, AC004486.1.
- chr12:48,039,784–48,106,079, 5 genes, copy number 9: AC004801.6, SENP1, AC004801.2, RNU6-1203P, AC004801.1.
- chr12:52,069,246–52,223,813, 7 genes, copy number 11 (within-gene range 2–11): ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1, LINC00592, KRT80.
- chr12:55,019,974–55,427,192, 22 genes, copy number 7–25: NEUROD4, OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76.
- chr12:55,444,069–55,493,316, 3 genes, copy number 25: OR6C2, OR6C70, OR6C68.
- chr12:57,216,794–58,813,060, 64 genes, copy number 16–22 (within-gene range 2–22) (broad region; genes not listed).
- chr12:60,150,187–60,363,935, 4 genes, copy number 12 (within-gene range 2–12): AC087883.2, AC087883.1, Y_RNA, AC090022.1.
- chr12:65,017,468–65,248,355, 6 genes, copy number 10–22: AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2.
- chr12:65,281,657–65,286,728, 1 gene, copy number 22: AC026124.1.
- chr12:65,758,020–65,966,291, 5 genes, copy number 25 (within-gene range 2–25): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:67,929,235–67,970,017, 1 gene, copy number 10 (within-gene range 1–10): LINC01479.
- chr12:68,143,318–68,553,882, 11 genes, copy number 6–20: AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12.
- chr12:68,805,011–68,850,686, 5 genes, copy number 37: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:69,212,108–70,543,040, 31 genes, copy number 21–37 (within-gene range 2–37): AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1.
- chr12:71,007,773–71,927,248, 19 genes, copy number 10–35 (within-gene range 1–35): AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:72,087,266–72,670,758, 1 gene, copy number 19 (within-gene range 1–19): TRHDE.
- chr12:72,431,722–72,611,316, 2 genes, copy number 19: H3P35, CHCHD3P2.
- chr12:75,020,969–75,044,793, 1 gene, copy number 14: AC073525.1.
- chr12:76,562,294–76,722,286, 6 genes, copy number 21: AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43.
- chr12:76,984,079–77,065,569, 2 genes, copy number 17: AC025161.1, E2F7.
- chr12:84,859,491–85,036,277, 3 genes, copy number 16 (within-gene range 2–16): SLC6A15, AC128657.1, TSPAN19.
- chr16:46,469,341–47,464,149, 31 genes, copy number 11 (within-gene range 2–11): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 7,165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
